Somatic mutation profile of tumor specimen TCGA-76-6662-01A (aliquot TCGA-76-6662-01A-11D-1845-08) from TCGA case TCGA-76-6662, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.9 years (21,511 days).
Specimen TCGA-76-6662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a39a333-74a9-4a9f-8334-b1913ba70b36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6662-10A (Blood Derived Normal), aliquot TCGA-76-6662-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b3337f8-7d53-455e-afe3-5a0f6378150d

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 24, Silent 10, Nonsense Mutation 3, Frame Shift Del 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1354_1356dup p.Y452dup (on ENST00000521381 / NM_181523.3; = p.Y182dup on NM_181504.4) | In Frame Ins (INS) | VAF 24/88 reads (27%) | hotspot (GDC flag); catalogued as COSV57142832; called by mutect2, pindel, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRV1 | c.4603G>A p.E1535K | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs761612567, COSV67988588; called by muse, mutect2, varscan2
- AMY2B | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 58/907 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs370144544; called by muse, mutect2
- ANXA3 | c.238T>A p.F80I | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV53715425; called by muse, mutect2, varscan2
- ARHGEF26 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV62848263; called by muse, mutect2, varscan2
- ATP6V1C1 | c.388A>C p.T130P | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as rs927928664, COSV67778346; called by muse, mutect2, varscan2
- ICAM1 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as rs141326678; called by muse, mutect2, varscan2
- IGF1R | c.1814G>T p.R605L | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.135); catalogued as CM128294, COSV51306239; called by muse, mutect2, varscan2
- IMPG1 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.041); catalogued as rs370162508, COSV64055755; called by muse, mutect2, varscan2
- KIF20B | c.3454C>A p.L1152I (on ENST00000371728 / NM_001284259.2; = p.L1112I on NM_016195.4) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); catalogued as COSV53309871; called by muse, mutect2, varscan2
- KLK6 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as rs553226234, COSV100037844, COSV59564993; called by muse, mutect2, varscan2
- LILRA5 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.509); catalogued as rs758851272, COSV56643559; called by muse, mutect2, varscan2
- OR2L3 | c.750C>A p.Y250* | Nonsense Mutation (SNP) | VAF 41/167 reads (25%) | catalogued as COSV63455525; called by mutect2, varscan2
- OR5D18 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV61737658; called by muse, mutect2, varscan2
- PCOLCE2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs143959509; called by muse, mutect2, varscan2
- REM2 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57465706; called by muse, mutect2, varscan2
- REPIN1 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV68292524; called by muse, mutect2
- RXRA | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV62683646; called by muse, varscan2
- SCN1B | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs180943300; ClinVar: uncertain significance; called by muse, mutect2
- SPTBN4 | c.5560C>T p.R1854W | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58953050; called by muse, mutect2, varscan2
- STK10 | c.2130G>A p.M710I | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV51575646; called by muse, mutect2, varscan2
- TCHH | c.5339G>A p.R1780H | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV100915174, COSV64273456; called by muse, mutect2, varscan2
- TP53 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM942116, CM983475, COSV52661607, COSV52839281, COSV53396164; called by muse, mutect2, varscan2
- TTN | c.101174G>T p.G33725V (on ENST00000591111; = p.G26301V on NM_003319.4) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | PolyPhen probably damaging (0.993); catalogued as COSV60153495, COSV60245235; called by muse, mutect2, varscan2
- UGT2A3 | c.388T>C p.Y130H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.927); catalogued as COSV52360756; called by muse, mutect2, varscan2
- ULBP1 | c.589T>G p.F197V | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs781482414, COSV57664528; called by muse, mutect2, varscan2
- ZAN | c.4634C>T p.S1545L | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as rs377250580; called by muse, mutect2, varscan2
- NAA35 | c.370_371del p.S124Tfs*13 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- PLEKHG1 | c.2234dup p.G746Rfs*11 | Frame Shift Ins (INS) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- RB1 | c.409_412del p.E137Lfs*15 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | called by mutect2, pindel, varscan2
- ABI3 | c.648C>T p.S216= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs1211891945, COSV56800605; called by muse, mutect2, varscan2
- DNAH17 | c.9051C>T p.P3017= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV67757281; called by muse, mutect2, varscan2
- KIF25 | c.870G>A p.A290= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs371921249; called by muse, mutect2, varscan2
- MAML2 | c.1428G>A p.G476= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV73263898; called by muse, mutect2, varscan2
- PLCB2 | c.1101C>T p.D367= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs375119309; called by muse, mutect2, varscan2
- TBCD | c.1683G>A p.Q561= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV62802920; called by muse, mutect2, varscan2
- TENM3 | c.6744T>C p.F2248= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV69312069; called by muse, mutect2, varscan2
- TKTL2 | c.1203C>T p.F401= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs756397639, COSV54921591; called by muse, mutect2, varscan2
- TTN | c.41298C>T p.D13766= (on ENST00000591111; = p.D6342= on NM_003319.4) | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as rs370808856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR11 | c.2289T>C p.N763= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV54789965; called by muse, mutect2, varscan2
